PECGS case C083-000025 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/44ccc30a-c8b0-4da6-a8fc-f140ec649625

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 60 years; Year of birth: 1961; Vital status: Dead; Cause of death: Cancer Related; Education level: High School Graduate or GED.

Diagnoses (1)
1. Adenocarcinoma with mixed subtypes: ICD-O-3 morphology code: 8255/3; Tissue or organ of origin: Cecum; Age at diagnosis: 60.1 years (21,952 days); AJCC pathologic stage: Stage IV; Progression or recurrence: yes; Days to last follow up: 32 days.

Other clinical attributes
- Menopause status: Postmenopausal.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 11.25.

Biospecimens (2 samples)
- Sample C083-000025_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000025_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
